Somatic mutation profile of tumor specimen MMRF_1055_1_BM_CD138pos (aliquot MMRF_1055_1_BM_CD138pos_T1_KBS5U_L02853) from MMRF case MMRF_1055, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,428 days).
Specimen MMRF_1055_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfcbe1b0-21b8-4b61-bc2f-4977aba4fc0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1055_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1055_1_PB_WBC_C3_KBS5U_L02865; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b8fee7-c11e-43db-b446-1561fc5aab5e

The open-access MAF lists 99 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 23, Intron 11, Silent 8, 5'UTR 7, Frame Shift Del 4, 3'Flank 4, Nonsense Mutation 3, RNA 3, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- FAM171A1 | c.2332C>T p.R778* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as rs1195052251; called by muse, mutect2, varscan2
- HAUS6 | c.2342del p.P781Rfs*7 | Frame Shift Del (DEL) | VAF 54/205 reads (26%) | catalogued as COSV100997936; called by mutect2, pindel, varscan2
- HELZ2 | c.2059G>A p.G687S (on ENST00000467148 / NM_001037335.2; = p.G118S on NM_033405.3) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs754364453; called by muse, mutect2, varscan2
- IGLV3-22 | c.157T>C p.W53R | Missense Mutation (SNP) | VAF 128/144 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747257568; called by muse, varscan2
- KIF21B | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 76/87 reads (87%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs866365757, COSV100144819, COSV59759564; called by muse, mutect2, varscan2
- LRCH3 | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1009783550; called by muse, mutect2, varscan2
- MYCBP2 | c.8855G>A p.R2952Q (on ENST00000357337; = p.R2990Q on NM_015057.5) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs780450049, COSV62017122; called by muse, mutect2, varscan2
- OR9Q2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs762084232; called by muse, mutect2, varscan2
- OSBPL6 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs779160281, COSV51910535; called by muse, mutect2, varscan2
- PCDHA3 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as rs991420459; called by muse, mutect2, varscan2
- PXDN | c.4040C>T p.P1347L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs368855044; called by muse, mutect2, varscan2
- RYR1 | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150442096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5B | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs760351333; called by muse, mutect2, varscan2
- SEMG1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs150756174, COSV54871744; called by muse, mutect2, varscan2
- UNK | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179208158, COSV53143243; called by muse, mutect2, varscan2
- WDR25 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs768269075, COSV58934708; called by muse, mutect2, varscan2
- ZFPM2 | c.2798C>T p.S933L | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.17); catalogued as rs1376349550, COSV65876295; called by muse, mutect2, varscan2
- ZMYND10 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs764019296, COSV51604136; called by muse, mutect2, varscan2
- AASDHPPT | c.682T>C p.W228R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.2482G>A p.A828T (on ENST00000506720 / NM_001322402.2; = p.A760T on NM_015236.6) | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- AGAP2 | c.211C>G p.H71D | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ARHGAP28 | c.1580A>T p.K527I (on ENST00000383472 / NM_001366230.1; = p.K368I on NM_001010000.3) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- COX8A | c.135del p.S46Pfs*4 | Frame Shift Del (DEL) | VAF 67/142 reads (47%) | called by mutect2, pindel, varscan2
- CRELD2 | c.1009+8G>A | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GC | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIC1 | c.1310dup p.Y437* (on ENST00000322941 / NM_001098202.1; = p.Y418* on NM_006497.4) | Nonsense Mutation (INS) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- IDH2 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- IGHV2-70D | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, varscan2
- IGHV2-70D | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- KRTAP5-5 | c.549del p.C184Afs*67 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by muse*, mutect2, varscan2*
- KRTAP5-5 | c.551_579del p.C184Lfs*7 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by muse*, mutect2
- MARK2 | c.1653T>A p.S551R (on ENST00000402010 / NM_001039469.2; = p.S517R on NM_017490.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTERF4 | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- RAB40AL | c.604T>C p.S202P | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RABGAP1 | c.2035G>T p.G679W | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF168 | c.1352T>C p.L451S | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SIX1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- STING1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TCERG1 | c.1532T>G p.M511R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ZNF66 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP2 | c.588C>T p.F196= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs778518117, COSV70097717; called by muse, mutect2, varscan2
- ERAP2 | c.1975A>C p.R659= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as rs1164585162; called by muse, mutect2, varscan2
- FAM83B | c.192T>C p.I64= | Silent (SNP) | VAF 85/192 reads (44%) | called by muse, mutect2, varscan2
- KLK1 | c.732C>T p.A244= | Silent (SNP) | VAF 72/118 reads (61%) | catalogued as rs199823924; called by muse, mutect2, varscan2
- LIMD2 | c.90C>T p.F30= | Silent (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- MCHR1 | c.861C>A p.A287= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- PTPRM | c.483G>C p.V161= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV59853959; called by muse, mutect2
- VARS1 | c.2631C>T p.I877= | Silent (SNP) | VAF 84/164 reads (51%) | catalogued as rs1241876990, COSV63304394; called by muse, mutect2
- ABLIM3 | c.*67G>A | 3'UTR (SNP) | VAF 70/370 reads (19%) | catalogued as rs571104946; called by muse, mutect2, varscan2
- ADAMTS9 | c.1464-460G>A | Intron (SNP) | VAF 27/98 reads (28%) | catalogued as rs1268870689; called by muse, mutect2, varscan2
- ARFGEF3 | c.*6980del | 3'UTR (DEL) | VAF 26/55 reads (47%) | catalogued as rs553484955; called by mutect2, varscan2
- ARL6IP5 | c.*676A>T | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- ATP6V0E2 | c.*231G>A | 3'UTR (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- BCL2L1 | c.-155del | 5'UTR (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel
- BMP6 | c.*782_*816del | 3'UTR (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel
- CEP170 | c.1843+302T>A | Intron (SNP) | VAF 2/12 reads (17%) | catalogued as rs2789178; called by muse, mutect2
- CNNM3 | c.*161C>T | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- COG2 | c.*385C>T | 3'UTR (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- COMTD1 | c.94+32G>A | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, varscan2
- CSPG5 | c.-1460_-1457del | 5'UTR (DEL) | VAF 45/149 reads (30%) | called by mutect2, pindel, varscan2
- EIF3J | c.*788T>G | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- FAT3 | c.*1819C>T | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- GALNTL6 | c.138+689T>G | Intron (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- GPM6B | chrX:13773480 T>G | 3'Flank (SNP) | VAF 37/45 reads (82%) | called by muse, mutect2, varscan2
- GPR171 | c.*538A>C | 3'UTR (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- GTF3C4 | c.*4119C>T | 3'UTR (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- H3C7 | c.*24C>G | 3'UTR (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- HDAC7 | chr12:47783631 G>A | 3'Flank (SNP) | VAF 15/43 reads (35%) | catalogued as rs559839936; called by muse, mutect2, varscan2
- ICE2 | c.-172C>T | 5'UTR (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- IGHV1-3 | c.-26A>G | 5'UTR (SNP) | VAF 14/17 reads (82%) | catalogued as rs1555419273; called by muse, varscan2
- KALRN | c.4929+22519T>A | Intron (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- KCNQ4 | c.*1020C>T | 3'UTR (SNP) | VAF 78/134 reads (58%) | catalogued as rs1018777373; called by muse, mutect2, varscan2
- NORAD | n.452G>A | RNA (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- NRXN1 | c.-673T>C | 5'UTR (SNP) | VAF 37/62 reads (60%) | called by muse, varscan2
- NRXN1 | c.-719G>A | 5'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, varscan2
- PARP11 | c.*1017T>C | 3'UTR (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- PAX6 | chr11:31789655 A>G | 3'Flank (SNP) | VAF 52/160 reads (33%) | called by muse, mutect2, varscan2
- PLA2G2F | c.*1801C>T | 3'UTR (SNP) | VAF 63/109 reads (58%) | catalogued as rs568315189, COSV64280259; called by muse, mutect2, varscan2
- PPP1R15B | c.*1155A>C | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- PSAPL1 | c.*2398C>T | 3'UTR (SNP) | VAF 44/118 reads (37%) | catalogued as rs554674514; called by muse, mutect2, varscan2
- RILPL1 | chr12:123536462 T>C | 5'Flank (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- RNU1-5P | chr1:16871101 C>T | 5'Flank (SNP) | VAF 28/230 reads (12%) | called by muse, mutect2
- RPL28 | c.-8-56T>A | Intron (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- RPL9 | c.-2+153C>T | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as rs1560662424; called by muse, mutect2, varscan2
- SCIN | c.*140G>A | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- SIDT2 | c.2105+93A>G | Intron (SNP) | VAF 107/351 reads (30%) | catalogued as rs543417424; called by muse, mutect2, varscan2
- SLC35F2 | c.*1440T>C | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- SPATA8 | n.1255C>A | RNA (SNP) | VAF 44/176 reads (25%) | called by muse, mutect2, varscan2
- TLE5 | c.297+104C>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- TOLLIP | c.*1089T>G | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- TOP1 | c.*237del | 3'UTR (DEL) | VAF 50/144 reads (35%) | called by mutect2, pindel, varscan2
- TOX3 | c.907-37T>C | Intron (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- VN1R10P | n.560T>C | RNA (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071802 G>A | 3'Flank (SNP) | VAF 3/46 reads (7%) | catalogued as rs1450741307; called by muse, mutect2
- WDR38 | c.-64C>T | 5'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- ZBTB33 | c.*1038G>A | 3'UTR (SNP) | VAF 33/37 reads (89%) | called by muse, mutect2, varscan2
- ZNF280D | c.*54_*61del | 3'UTR (DEL) | VAF 145/776 reads (19%) | called by mutect2, pindel, varscan2
- ZNF280D | c.381+1376C>T | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
